MMRF case MMRF_1967 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/09f10d15-16d9-49c0-973b-23082be323d7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.1 years (27,080 days); ISS stage: II; Days to last known disease status: 1,006 days (2.8 years); Days to last follow up: 1,006 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 166 days; Days to treatment end: 166 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 167 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 0): M Protein 2.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 1.36 g/L; Immunoglobulin A 42.1 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.87 µg/mL; Lactate Dehydrogenase 1.65 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 38.3 g/L; Total Protein 8.5 g/dL; Glucose 9.68 mmol/L.
- Day 74 (ECOG 1): Immunoglobulin G 1.67 g/L; Immunoglobulin A 14 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 6.6 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 5.72 mmol/L.
- Day 186 (ECOG 1): Lactate Dehydrogenase 9.64 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 28 g/L; Total Protein 4.9 g/dL; Glucose 8.42 mmol/L.
- Day 285 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 4.87 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 1.54 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 91.1 µmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 6.22 mmol/L.
- Day 348 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 5.92 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 1.06 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 5.83 mmol/L.
- Day 446 (ECOG 0): Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 48 g/L; Total Protein 6.7 g/dL; Glucose 6.38 mmol/L.
- Day 529 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 4.66 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 6.38 mmol/L.
- Day 642 (ECOG 0): Hemoglobin 7.25 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 185 ×10⁹/L.
- Day 732 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 1.4 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 7.81 mmol/L.
- Day 809 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 4.56 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.8 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 9.46 mmol/L.
- Day 900 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 4.35 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.8 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 1,006 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 5.25 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 1.16 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day -1: Weight: 93 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1967_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1967_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
